Somatic mutation profile of tumor specimen ER-ABF0-TTP1-A (aliquot ER-ABF0-TTP1-A-1-0-D-A46M-35) from EXCEPTIONAL_RESPONDERS case ER-ABF0, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 52.1 years (19,042 days).
Specimen ER-ABF0-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d9a98a9e-6381-49b3-82ce-2c3ebeb2d00b.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ER-ABF0-NB1-A (Blood Derived Normal), aliquot ER-ABF0-NB1-A-1-0-D-A76E-35; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0de9f6cd-9a0d-4057-8242-5b4e76bb3307

The open-access MAF lists 13 somatic variants for this specimen: 7 protein-altering or splice-affecting, 6 silent.
By variant classification: Silent 6, Missense Mutation 4, Splice Site 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.560-1G>T p.X187_splice | Splice Site (SNP) | VAF 137/446 reads (31%) | hotspot (GDC flag); catalogued as CD043957, CS011574, CS083991, COSV52662318, COSV52676510, COSV52683087, COSV52690533; called by muse, mutect2, varscan2
- BRIP1 | c.1802C>G p.S601* | Nonsense Mutation (SNP) | VAF 50/444 reads (11%) | called by mutect2, varscan2
- KMT2D | c.10611G>C p.K3537N | Missense Mutation (SNP) | VAF 33/358 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MSH6 | c.2911G>C p.G971R | Missense Mutation (SNP) | VAF 58/511 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PHLPP2 | c.3516C>A p.H1172Q | Missense Mutation (SNP) | VAF 156/444 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- POLE | c.6082A>G p.R2028G | Missense Mutation (SNP) | VAF 18/356 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2
- TOP1 | c.985_992del p.E329* | Frame Shift Del (DEL) | VAF 48/325 reads (15%) | called by pindel, varscan2
- CDH20 | c.501C>T p.D167= | Silent (SNP) | VAF 34/313 reads (11%) | catalogued as rs150943040; called by muse, mutect2, varscan2
- GRIN2A | c.3576C>A p.T1192= | Silent (SNP) | VAF 55/495 reads (11%) | catalogued as rs768172880, COSV58034013; called by muse, mutect2, varscan2
- KLHL6 | c.1161A>G p.T387= | Silent (SNP) | VAF 122/504 reads (24%) | called by muse, varscan2
- NFKBIA | c.486C>T p.V162= | Silent (SNP) | VAF 58/344 reads (17%) | called by muse, mutect2, varscan2
- PIK3CG | c.648C>T p.A216= | Silent (SNP) | VAF 54/382 reads (14%) | catalogued as COSV63249472; called by muse, mutect2, varscan2
- ROS1 | c.4062T>C p.F1354= | Silent (SNP) | VAF 38/414 reads (9%) | called by muse, mutect2
